Somatic mutation profile of tumor specimen ALCH-B464-TTP1-A (aliquot ALCH-B464-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B464, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 61.7 years (22,538 days).
Specimen ALCH-B464-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8dcbae8-3a79-47a4-ab67-8ef1a623ab6e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B464-NB1-A (Blood Derived Normal), aliquot ALCH-B464-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af82a14e-f4dc-4084-b842-b46905265dff

The open-access MAF lists 89 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 18, Nonsense Mutation 6, Intron 4, RNA 4, Splice Site 4, 5'Flank 3, 3'Flank 1, 5'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.797G>T p.G266V | Missense Mutation (SNP) | VAF 26/306 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ACSM2A | c.274C>A p.Q92K (on ENST00000219054; = p.Q13K on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/316 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.132); catalogued as COSV54582527, COSV54584050; called by muse, mutect2
- AQP12B | c.94G>T p.G32C | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs776749172; called by muse, mutect2, varscan2
- AQP8 | c.217G>T p.G73W | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54845439, COSV54845888; called by muse, mutect2, varscan2
- CDH10 | c.404G>T p.R135I | Missense Mutation (SNP) | VAF 19/487 reads (4%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs1261442492, COSV100049919, COSV52591381; called by muse, mutect2
- DACT2 | c.1837G>A p.V613M | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.018); catalogued as rs1474044975, COSV64694174; called by muse, mutect2
- KRT6B | c.1140G>T p.E380D | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV99360968; called by muse, mutect2
- KRT83 | c.594-1G>A p.X198_splice | Splice Site (SNP) | VAF 25/339 reads (7%) | catalogued as rs758786488; called by muse, mutect2
- LSMEM1 | c.172G>T p.G58* | Nonsense Mutation (SNP) | VAF 28/320 reads (9%) | catalogued as COSV57197285; called by muse, mutect2
- NPSR1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 33/320 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as rs375118842, COSV100706872; called by muse, mutect2
- NR2F1 | c.344G>T p.R115L | Missense Mutation (SNP) | VAF 21/295 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM140842; called by muse, mutect2
- NRP2 | c.2716G>T p.E906* (on ENST00000360409 / NM_201266.2; = p.E901* on NM_003872.3) | Nonsense Mutation (SNP) | VAF 8/134 reads (6%) | catalogued as COSV63377307; called by muse, mutect2
- PDCL3 | c.596C>G p.S199C | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV51810357; called by muse, mutect2
- PDE10A | c.659G>T p.W220L | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV100606092; called by muse, mutect2, varscan2
- PDGFRA | c.2465G>T p.R822L | Missense Mutation (SNP) | VAF 26/378 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57270253, COSV57271649; called by muse, mutect2
- PTH1R | c.491G>T p.W164L | Missense Mutation (SNP) | VAF 14/254 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); catalogued as COSV57317724; called by muse, mutect2
- SAXO1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 7/137 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.326); catalogued as rs1164188894; called by muse, mutect2
- SLC25A21 | c.71-1G>A p.X24_splice | Splice Site (SNP) | VAF 14/147 reads (10%) | catalogued as rs961953393, COSV100492572; called by muse, mutect2
- TENM1 | c.4087C>T p.R1363* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV64427949; called by muse, mutect2
- TPH2 | c.1025C>A p.A342E | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs755764502; called by muse, mutect2
- ZNF699 | c.1006G>T p.E336* | Nonsense Mutation (SNP) | VAF 15/142 reads (11%) | catalogued as COSV58024861; called by muse, mutect2, varscan2
- AFG3L2 | c.552+1G>T p.X184_splice | Splice Site (SNP) | VAF 21/338 reads (6%) | called by muse, mutect2
- AGTR1 | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 8/245 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2
- ATP5F1D | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- B3GALT2 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.444); called by muse, mutect2
- CHD5 | c.4247G>T p.G1416V | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, varscan2
- CHST7 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLEC4A | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- CNKSR2 | c.1030G>C p.D344H | Missense Mutation (SNP) | VAF 30/228 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CNTNAP5 | c.2273C>A p.P758H | Missense Mutation (SNP) | VAF 10/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- COL6A5 | c.7757A>G p.K2586R (on ENST00000312481; = p.K2582R on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/207 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.084); called by muse, mutect2
- CRYBB3 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 14/284 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2
- CSNK2A1 | c.1022G>T p.G341V | Missense Mutation (SNP) | VAF 16/230 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2
- DMD | c.236dup p.A80Gfs*9 | Frame Shift Ins (INS) | VAF 25/212 reads (12%) | called by mutect2, pindel, varscan2
- DNASE1L3 | c.621G>C p.L207F | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- DRGX | c.499G>C p.A167P | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.69); called by muse, mutect2
- FOXG1 | c.1269C>A p.H423Q | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); called by muse, mutect2
- GPC3 | c.238A>T p.K80* | Nonsense Mutation (SNP) | VAF 15/136 reads (11%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.226G>C p.D76H | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- KDM5C | c.2162_2183del p.C721Lfs*36 | Frame Shift Del (DEL) | VAF 8/109 reads (7%) | called by mutect2, pindel
- PLD5 | c.1112T>C p.L371S (on ENST00000442594; = p.L309S on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.726); called by muse, mutect2
- PRDM9 | c.1335C>A p.H445Q | Missense Mutation (SNP) | VAF 40/736 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2
- PRKG1 | c.1001+1G>T p.X334_splice | Splice Site (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- PRMT8 | c.118G>T p.A40S | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTH1R | c.492G>T p.W164C | Missense Mutation (SNP) | VAF 16/254 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RASA2 | c.1949A>G p.Y650C | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2
- SCN1A | c.170C>G p.A57G | Missense Mutation (SNP) | VAF 18/392 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SEMA3A | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- SHE | c.833G>T p.S278I | Missense Mutation (SNP) | VAF 11/258 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.347); called by muse, mutect2
- SLIT2 | c.3685A>T p.I1229F | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.061); called by muse, mutect2
- SYNPO2 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TBC1D12 | c.1483A>G p.S495G | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); called by muse, mutect2
- TET1 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 13/240 reads (5%) | called by muse, mutect2
- TUBB8B | c.351G>T p.M117I | Missense Mutation (SNP) | VAF 25/534 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2
- UNC45B | c.578C>A p.P193H | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- XKR5 | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 12/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF208 | c.2845G>T p.A949S | Missense Mutation (SNP) | VAF 12/237 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.263); called by muse, mutect2
- ZNF438 | c.2293C>G p.L765V | Missense Mutation (SNP) | VAF 12/158 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0.053); called by muse, mutect2
- ADD3 | c.756A>G p.Q252= | Silent (SNP) | VAF 11/105 reads (10%) | called by muse, mutect2, varscan2
- AMER1 | c.1395C>A p.P465= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- AP3B2 | c.1734G>T p.R578= | Silent (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- CPEB4 | c.444C>A p.A148= | Silent (SNP) | VAF 17/228 reads (7%) | called by muse, mutect2
- CRB1 | c.3126A>T p.T1042= | Silent (SNP) | VAF 28/480 reads (6%) | called by muse, mutect2
- FGD5 | c.3423G>T p.L1141= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as COSV99549770; called by muse, mutect2
- HSCB | c.99G>A p.Q33= | Silent (SNP) | VAF 14/210 reads (7%) | called by muse, mutect2
- JUP | c.1788G>A p.S596= | Silent (SNP) | VAF 3/18 reads (17%) | catalogued as rs1484071882; called by muse, varscan2
- LETM1 | c.276T>G p.S92= | Silent (SNP) | VAF 32/337 reads (9%) | called by muse, mutect2
- LILRB4 | c.90C>G p.T30= | Silent (SNP) | VAF 9/86 reads (10%) | catalogued as COSV54408843, COSV54409242; called by muse, mutect2, varscan2
- NLRP12 | c.3027C>A p.A1009= | Silent (SNP) | VAF 22/320 reads (7%) | called by muse, mutect2
- PCDHA6 | c.291G>A p.G97= | Silent (SNP) | VAF 14/364 reads (4%) | called by muse, mutect2
- PXDN | c.2946G>T p.L982= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV99414016; called by muse, mutect2, varscan2
- SERPINB4 | c.858G>T p.R286= | Silent (SNP) | VAF 23/252 reads (9%) | called by muse, mutect2
- SPTA1 | c.417G>T p.L139= | Silent (SNP) | VAF 22/347 reads (6%) | called by muse, mutect2
- TASOR2 | c.6882A>G p.T2294= | Silent (SNP) | VAF 12/258 reads (5%) | catalogued as rs1262737160; called by muse, mutect2
- ZDBF2 | c.3435T>C p.H1145= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- ZEB2 | c.2070A>G p.E690= | Silent (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- AC009237.3 | n.473G>T | RNA (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- AC011462.1 | c.211-12822G>T | Intron (SNP) | VAF 18/287 reads (6%) | called by muse, mutect2
- COTL1 | c.-11G>T | 5'UTR (SNP) | VAF 6/47 reads (13%) | catalogued as rs1384731443; called by muse, mutect2, varscan2
- PRDM11 | chr11:45227185 A>T | 3'Flank (SNP) | VAF 10/115 reads (9%) | called by muse, mutect2
- SERTAD4 | c.-18+650C>T | Intron (SNP) | VAF 10/125 reads (8%) | catalogued as rs774524646; called by muse, mutect2
- SLC5A1 | chr22:32039612 C>G | 5'Flank (SNP) | VAF 18/350 reads (5%) | called by muse, mutect2
- SPATA31C1 | n.1084C>T | RNA (SNP) | VAF 20/281 reads (7%) | catalogued as rs1192651191; called by muse, mutect2
- SPATA31C2 | n.420G>T | RNA (SNP) | VAF 32/404 reads (8%) | called by muse, mutect2
- TTN | c.10361-3979C>T | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- TUBB7P | n.72C>G | RNA (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- TUBGCP2 | c.616+576G>T | Intron (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- WT1 | chr11:32438816 C>G | 5'Flank (SNP) | VAF 23/577 reads (4%) | called by muse, mutect2
- ZKSCAN8 | chr6:28136979 A>T | 5'Flank (SNP) | VAF 22/226 reads (10%) | called by muse, mutect2
